Somatic mutation profile of cancer-model specimen HCM-CSHL-0853-C56-85B (3D Organoid, passage 8; aliquot HCM-CSHL-0853-C56-85B-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0853-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: High Grade.
Specimen HCM-CSHL-0853-C56-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ab0cd04-16e3-41e8-8276-741455478dc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0853-C56-10A (Blood Derived Normal), aliquot HCM-CSHL-0853-C56-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0c49a26-0552-4bf6-8a15-e6b6b971aae7

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 8, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 172/209 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C2CD2L | c.2038G>A p.A680T | Missense Mutation (SNP) | VAF 305/1028 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.187); catalogued as rs940210543; called by muse, mutect2, varscan2
- CFAP47 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 217/282 reads (77%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs760933446, COSV52884417; called by muse, mutect2, varscan2
- CNOT1 | c.4196G>A p.R1399Q | Missense Mutation (SNP) | VAF 206/262 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV55320287; called by muse, mutect2, varscan2
- CTNNA2 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 85/201 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as COSV58173470; called by muse, mutect2, varscan2
- DOCK8 | c.6136C>A p.L2046I | Missense Mutation (SNP) | VAF 178/214 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs747086561; called by muse, mutect2, varscan2
- FAM160A2 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 218/491 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768160220; called by muse, mutect2, varscan2
- FLT3 | c.2440G>A p.A814T | Missense Mutation (SNP) | VAF 144/345 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201208287, COSV54046882, COSV54065904; called by muse, mutect2, varscan2
- PPFIA4 | c.2323G>C p.D775H (on ENST00000447715; = p.D776H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 166/407 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs774650502; called by muse, mutect2, varscan2
- FRRS1 | c.191T>G p.I64S | Missense Mutation (SNP) | VAF 89/230 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, varscan2
- GRSF1 | c.352A>G p.S118G | Missense Mutation (SNP) | VAF 152/353 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ITIH4 | c.1168G>C p.V390L | Missense Mutation (SNP) | VAF 109/141 reads (77%) | SIFT tolerated (0.19); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- NLRC5 | c.1657G>T p.A553S | Missense Mutation (SNP) | VAF 68/356 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NLRC5 | c.1658C>A p.A553D | Missense Mutation (SNP) | VAF 71/363 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- OR8B8 | c.44C>A p.A15E | Missense Mutation (SNP) | VAF 28/628 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); called by muse, mutect2
- PRSS36 | c.2477G>A p.S826N | Missense Mutation (SNP) | VAF 306/391 reads (78%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- RCN3 | c.953G>C p.G318A | Missense Mutation (SNP) | VAF 174/215 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC6A14 | c.1658A>T p.Y553F | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- SPATA18 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 183/428 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- AP3B1 | c.1932C>T p.P644= | Silent (SNP) | VAF 73/88 reads (83%) | catalogued as rs368771979; called by muse, mutect2, varscan2
- BABAM2 | c.1125G>A p.E375= | Silent (SNP) | VAF 144/318 reads (45%) | called by muse, mutect2, varscan2
- COL7A1 | c.6897A>G p.G2299= | Silent (SNP) | VAF 158/213 reads (74%) | catalogued as rs749586805; called by muse, mutect2, varscan2
- KIAA1522 | c.777C>A p.T259= (on ENST00000373480 / NM_001198972.2; = p.T318= on NM_020888.3) | Silent (SNP) | VAF 322/731 reads (44%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.867C>T p.N289= | Silent (SNP) | VAF 227/305 reads (74%) | catalogued as rs374654639; called by muse, mutect2, varscan2
- NCAPH | c.687C>T p.N229= | Silent (SNP) | VAF 162/357 reads (45%) | catalogued as rs760742546; called by muse, mutect2, varscan2
- NR0B2 | c.138C>T p.P46= | Silent (SNP) | VAF 289/362 reads (80%) | catalogued as rs370821222; called by muse, mutect2, varscan2
- SHOC1 | c.2052G>A p.L684= | Silent (SNP) | VAF 126/261 reads (48%) | called by muse, mutect2, varscan2
- HSPB7 | chr1:16019339 del CTGT | 5'Flank (DEL) | VAF 279/665 reads (42%) | called by mutect2, pindel, varscan2
